Somatic mutation profile of tumor specimen TCGA-H7-A6C5-01A (aliquot TCGA-H7-A6C5-01A-11D-A30E-08) from TCGA case TCGA-H7-A6C5, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.2 years (23,808 days).
Specimen TCGA-H7-A6C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c214c294-341a-4f94-85c9-a26278ae7dea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H7-A6C5-10A (Blood Derived Normal), aliquot TCGA-H7-A6C5-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f09f0969-a372-4812-b482-08b6ede3df07

The open-access MAF lists 115 somatic variants for this specimen: 83 protein-altering or splice-affecting, 31 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 31, Nonsense Mutation 5, Frame Shift Del 4, In Frame Del 4, Splice Site 4, Frame Shift Ins 3, Intron 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 44/109 reads (40%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ADGRB3 | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV65409403, COSV65411202; called by muse, mutect2, varscan2
- ADGRF5 | c.2811G>T p.R937S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV99346352; called by muse, mutect2, varscan2
- AGBL2 | c.2565C>A p.C855* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100102057; called by muse, mutect2, varscan2
- ANKRD50 | c.3145C>T p.L1049F | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101539039; called by muse, mutect2, varscan2
- BIN1 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV99388485; called by muse, mutect2, varscan2
- CDH6 | c.1620A>T p.Q540H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV99420663; called by muse, mutect2, varscan2
- CDK8 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV67423403; called by muse, mutect2, varscan2
- CDPF1 | c.1-1G>T p.X1_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99415879; called by mutect2, varscan2
- CEPT1 | c.425G>T p.R142I | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853506, COSV64110985; called by muse, mutect2, varscan2
- CHD4 | c.1753C>T p.R585* (on ENST00000357008 / NM_001363606.2; = p.R598* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 81/289 reads (28%) | catalogued as COSV58906236; called by muse, mutect2, varscan2
- CHD7 | c.6562G>C p.E2188Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV101418412; called by muse, mutect2, varscan2
- CNGA2 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 98/146 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759242456, COSV100323920; called by muse, mutect2, varscan2
- COL19A1 | c.186C>A p.S62R | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100507372; called by muse, mutect2, varscan2
- DCLK2 | c.51A>T p.K17N | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99652677; called by muse, mutect2, varscan2
- DNAH11 | c.10666G>T p.G3556C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100177540; called by muse, mutect2, varscan2
- DNAH8 | c.11166-1G>C p.X3722_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100544036, COSV100547060; called by muse, varscan2
- DOCK8 | c.3745C>G p.Q1249E | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101210065; called by muse, mutect2, varscan2
- FAT3 | c.5849A>T p.H1950L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99970540; called by muse, mutect2, varscan2
- FAT3 | c.12352G>A p.G4118S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369315276; called by muse, varscan2
- FOXG1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100487048; called by muse, mutect2, varscan2
- GALNT2 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV100795883; called by muse, mutect2, varscan2
- GIT1 | c.78G>T p.R26S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99838403; called by muse, mutect2, varscan2
- GRIN3A | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs375779429, COSV62451129; called by muse, mutect2, varscan2
- IGSF11 | c.376C>A p.P126T (on ENST00000393775 / NM_001015887.3; = p.P125T on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100677832; called by muse, mutect2, varscan2
- IL13RA2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs782749009, COSV54567739; called by muse, mutect2, varscan2
- IMMT | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.04); catalogued as COSV99607584; called by muse, mutect2, varscan2
- JUN | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100973487, COSV64665079; called by muse, mutect2, varscan2
- KHDRBS2 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55473031, COSV99837090; called by muse, mutect2, varscan2
- KIDINS220 | c.2345A>G p.D782G | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876379; called by muse, mutect2, varscan2
- KIF7 | c.3655C>A p.H1219N | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99179620; called by muse, mutect2, varscan2
- LARGE1 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 23/174 reads (13%) | catalogued as COSV100506261; called by muse, mutect2, varscan2
- LRP2 | c.6694G>T p.G2232C | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99790046; called by muse, mutect2, varscan2
- MAPK14 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 21/70 reads (30%) | catalogued as COSV100005159; called by muse, mutect2, varscan2
- MMP16 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs1402438624, COSV54192771, COSV99690185; called by muse, mutect2, varscan2
- MOB1B | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100511640, COSV58673671; called by muse, mutect2, varscan2
- MORC1 | c.2911C>A p.H971N | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as COSV99227626; called by muse, mutect2
- MTMR11 | c.1001A>T p.E334V (on ENST00000439741 / NM_001145862.2; = p.E262V on NM_181873.3) | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99641396; called by muse, mutect2, varscan2
- NAV3 | c.884C>A p.S295Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV57096141, COSV99894997; called by muse, mutect2, varscan2
- NLRP11 | c.2343-1G>T p.X781_splice | Splice Site (SNP) | VAF 37/109 reads (34%) | catalogued as COSV100789806; called by muse, mutect2, varscan2
- NME8 | c.1127A>G p.E376G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as COSV99553805; called by muse, mutect2, varscan2
- NMI | c.311A>G p.Q104R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1365820064, COSV99693508; called by muse, mutect2, varscan2
- NXPH1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.078); catalogued as COSV101339793, COSV68310670; called by muse, mutect2, varscan2
- OR2H1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.17); catalogued as COSV101009914; called by muse, mutect2, varscan2
- PBRM1 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56274338, COSV99969360; called by muse, mutect2, varscan2
- PCDH15 | c.4445T>C p.V1482A | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.001); catalogued as COSV100226909; called by muse, mutect2, varscan2
- PCDHB4 | c.638C>A p.A213E | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52024319, COSV99522478; called by muse, mutect2, varscan2
- PCK2 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374328821; called by muse, mutect2, varscan2
- PSG6 | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 114/415 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); catalogued as COSV51834487; called by muse, mutect2, varscan2
- PUS10 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100369346, COSV100369739; called by muse, mutect2, varscan2
- PYGM | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99377573; called by muse, mutect2, varscan2
- RIPK4 | c.620A>G p.Y207C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100205335; called by muse, mutect2, varscan2
- RNF213 | c.7414T>G p.F2472V | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV100301378; called by muse, mutect2, varscan2
- ROBO3 | c.2608C>A p.L870M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV101185164; called by muse, mutect2
- RPP30 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.664); catalogued as rs746046571, COSV99521020; called by muse, mutect2, varscan2
- SCN7A | c.2719C>A p.L907I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV101313351; called by muse, mutect2, varscan2
- SENP7 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1378227014, COSV100053810; called by muse, mutect2, varscan2
- SFI1 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV101192266; called by muse, mutect2, varscan2
- SLC6A2 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.178); catalogued as COSV54926042; called by muse, mutect2, varscan2
- SPAG9 | c.2978G>A p.C993Y (on ENST00000262013 / NM_001130528.3; = p.C979Y on NM_003971.6) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs139856934, COSV100005847; called by muse, mutect2, varscan2
- SRRM2 | c.7869_7892del p.S2641_S2648del | In Frame Del (DEL) | VAF 24/98 reads (24%) | catalogued as rs1358722891; called by muse*, mutect2
- TMEM132A | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as rs374644513; called by muse, mutect2, varscan2
- TTN | c.90226G>A p.V30076I (on ENST00000591111; = p.V22652I on NM_003319.4) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | PolyPhen benign (0.003); catalogued as rs150930737; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- USH2A | c.3860A>T p.K1287I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.273); catalogued as COSV100241799; called by muse, mutect2, varscan2
- WASF3 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 76/145 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs761308925, COSV100099435; called by muse, mutect2, varscan2
- WDR75 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV100134439; called by muse, varscan2
- XPO1 | c.757A>G p.K253E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV101294304; called by muse, mutect2, varscan2
- ZCCHC24 | c.523T>C p.C175R | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100959482, COSV64887700; called by muse, mutect2, varscan2
- ZFP36 | c.109G>A p.G37S (on ENST00000594442; = p.G31S on NM_003407.5) | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.024); catalogued as COSV99953976; called by muse, mutect2, varscan2
- ZNF33A | c.79C>T p.Q27* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV100275517, COSV100276172; called by muse, mutect2, varscan2
- AL359922.1 | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRG2B | c.449_458del p.R150Mfs*12 | Frame Shift Del (DEL) | VAF 38/256 reads (15%) | called by mutect2, pindel
- GLI2 | c.4486_4490del p.D1496Hfs*4 (on ENST00000361492 / NM_001374353.1; = p.D1513Hfs*4 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 71/242 reads (29%) | called by mutect2, pindel, varscan2
- JAG2 | c.3539_3543dup p.D1182Tfs*190 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | called by pindel, varscan2
- KBTBD12 | c.307_314del p.T103Yfs*41 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- NSD1 | c.4993_4995del p.P1665del | In Frame Del (DEL) | VAF 79/138 reads (57%) | called by mutect2, pindel, varscan2
- OR8B3 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.1); called by muse, varscan2
- RAD23A | c.94_108del p.I32_K36del | In Frame Del (DEL) | VAF 20/122 reads (16%) | called by mutect2, pindel, varscan2
- RMC1 | c.-30_19del | Translation Start Site (DEL) | VAF 16/69 reads (23%) | called by mutect2, pindel
- SAAL1 | c.1081_1110del p.Q361_P370del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- SCG5 | c.276dup p.N93Qfs*13 | Frame Shift Ins (INS) | VAF 67/250 reads (27%) | called by mutect2, pindel, varscan2
- THEMIS | c.1746del p.K583Sfs*8 | Frame Shift Del (DEL) | VAF 56/253 reads (22%) | called by mutect2, pindel, varscan2
- WDR75 | c.1452dup p.A485Sfs*7 | Frame Shift Ins (INS) | VAF 28/136 reads (21%) | called by pindel, varscan2
- ADCY9 | c.69G>A p.G23= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV99570794; called by muse, mutect2, varscan2
- AMELX | c.84T>C p.Y28= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as rs1222990781, COSV100499034; called by muse, mutect2, varscan2
- C6orf118 | c.633C>T p.S211= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as rs1483582699, COSV57812791; called by muse, mutect2
- CEP164 | c.3435G>T p.A1145= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs149964584, COSV54041227, COSV99634241; called by muse, mutect2, varscan2
- CETN1 | c.462C>T p.D154= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs757185455, COSV59121220, COSV59121700; called by muse, mutect2, varscan2
- COL1A2 | c.2550A>T p.G850= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs764720520, COSV99800915; called by muse, mutect2, varscan2
- GEMIN5 | c.3111C>T p.G1037= | Silent (SNP) | VAF 98/168 reads (58%) | catalogued as COSV99594268; called by muse, mutect2, varscan2
- IFNL3 | c.486A>C p.P162= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs544442278, COSV101308011; called by muse, mutect2, varscan2
- IGHV3-49 | c.300C>T p.A100= | Silent (SNP) | VAF 77/229 reads (34%) | called by muse, mutect2, varscan2
- KCNG4 | c.1539C>T p.A513= | Silent (SNP) | VAF 82/315 reads (26%) | catalogued as COSV100377158, COSV57583546; called by muse, mutect2, varscan2
- KCNQ3 | c.568C>A p.R190= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as COSV101196391, COSV104429886, COSV66473715; called by muse, mutect2, varscan2
- KIR2DL3 | c.315T>C p.T105= | Silent (SNP) | VAF 168/1193 reads (14%) | called by muse, mutect2, varscan2
- MAP4K4 | c.942C>T p.G314= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs777817077, COSV56334686; called by muse, mutect2, varscan2
- MCF2 | c.1476G>A p.L492= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as COSV100645099; called by muse, mutect2, varscan2
- NBAS | c.2859A>G p.L953= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs1207593672, COSV99871432; called by muse, mutect2, varscan2
- PDE6H | c.117A>G p.P39= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs766367744, COSV99844048; called by muse, mutect2, varscan2
- PLEKHA6 | c.246C>T p.F82= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs752962685, COSV55329580, COSV55330708; called by muse, mutect2, varscan2
- PPP1R26 | c.303C>T p.L101= | Silent (SNP) | VAF 42/110 reads (38%) | catalogued as rs201939322, COSV63354683; called by muse, mutect2, varscan2
- PTPRU | c.942C>T p.D314= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV60527259; called by muse, mutect2, varscan2
- RILPL1 | c.525C>T p.D175= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs755108953, COSV100526212, COSV61553447; called by muse, mutect2, varscan2
- RNF213 | c.7674C>G p.S2558= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV100301380; called by muse, mutect2, varscan2
- SALL1 | c.2283G>A p.P761= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs774128799, COSV51762410; called by muse, mutect2, varscan2
- SIM1 | c.1320G>C p.S440= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV53490653, COSV99492722; called by muse, mutect2, varscan2
- SLC13A1 | c.903C>A p.I301= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV99520386; called by muse, mutect2, varscan2
- SPAG1 | c.2514G>A p.P838= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs752704151, COSV52558756; called by muse, mutect2, varscan2
- TLR5 | c.1869T>C p.S623= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100643376; called by muse, mutect2, varscan2
- TPST1 | c.729C>T p.V243= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs139548967; called by muse, mutect2, varscan2
- USP21 | c.1140T>C p.S380= | Silent (SNP) | VAF 36/149 reads (24%) | catalogued as rs144266041; called by muse, mutect2, varscan2
- USP34 | c.1698C>T p.D566= | Silent (SNP) | VAF 61/222 reads (27%) | catalogued as rs747664551, COSV68403943; called by muse, mutect2, varscan2
- WWC2 | c.1023G>A p.E341= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs770795468, COSV100968585; called by muse, mutect2, varscan2
- ZBTB7A | c.354C>T p.A118= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs377496407, COSV100475916; called by muse, varscan2
- ATE1 | c.942+994A>G | Intron (SNP) | VAF 26/102 reads (25%) | catalogued as rs756440689, COSV99817645; called by muse, mutect2, varscan2
